CCDI case PBBLPX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/40be0748-cb36-499b-b6de-4a4584da1f12

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.8 years (1,759 days).

Biospecimens (4 samples)
- Sample 0DELJ6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DELJ9, 0DELKN (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DEP2M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
